MMRF case MMRF_1997 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/71d7cb4b-f82a-42f8-88a9-c4ed03466b6d

Demographics
Sex at birth: male; Race: black or african american; Age at index: 86 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 86.7 years (31,682 days); ISS stage: I; Days to last known disease status: 954 days (2.6 years); Days to last follow up: 954 days (2.6 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 787 days (2.2 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 7 days; Days to treatment end: 93 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 94 days; Days to treatment end: 241 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 473 days (1.3 years); Days to treatment end: 558 days (1.5 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 579 days (1.6 years); Days to treatment end: 705 days (1.9 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.88 mg/dL; Immunoglobulin G 9.82 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 2.6 µg/mL; Hemoglobin 6.26 mmol/L; Leukocytes 2.9 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 5.7 g/dL; Glucose 4.24 mmol/L.
- Day 94 (ECOG 1): M Protein 0.2 g/dL; Immunoglobulin G 4.6 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.34 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 4.66 ×10⁹/L; Absolute Neutrophil 3.01 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 5 g/dL; Glucose 4.79 mmol/L.
- Day 172 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.39 mg/dL; Immunoglobulin G 4.42 g/L; Hemoglobin 6.32 mmol/L; Leukocytes 2.8 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.28 mmol/L; Glucose 4.62 mmol/L.
- Day 290 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 15.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.71 mg/dL; Immunoglobulin G 6.54 g/L; Hemoglobin 5.46 mmol/L; Leukocytes 2.89 ×10⁹/L; Absolute Neutrophil 1.29 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 33 g/L; Total Protein 5 g/dL; Glucose 5.72 mmol/L.
- Day 346 (ECOG 3): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.02 mg/dL; Immunoglobulin G 7.26 g/L; Hemoglobin 4.84 mmol/L; Leukocytes 4.21 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.13 mmol/L; Albumin 31 g/L; Total Protein 5.2 g/dL; Glucose 4.57 mmol/L.
- Day 451 (ECOG 2): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 19.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.53 mg/dL; Immunoglobulin G 9.13 g/L; Hemoglobin 5.77 mmol/L; Leukocytes 3.12 ×10⁹/L; Absolute Neutrophil 1.48 ×10⁹/L; Platelets 109 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 33 g/L; Total Protein 5.6 g/dL; Glucose 4.18 mmol/L.
- Day 541 (ECOG 2): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.66 mg/dL; Immunoglobulin G 4.64 g/L; Hemoglobin 5.46 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.33 mmol/L; Albumin 34 g/L; Total Protein 5.2 g/dL; Glucose 5.12 mmol/L.
- Day 634 (ECOG 2): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.91 mg/dL; Immunoglobulin G 4.49 g/L; Immunoglobulin A 1.18 g/L; Immunoglobulin M 0.39 g/L; Hemoglobin 5.33 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.43 mmol/L; Albumin 36 g/L; Total Protein 5.1 g/dL; Glucose 4.4 mmol/L.
- Day 716 (ECOG 2): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 6.4 g/L; Immunoglobulin A 1.76 g/L; Immunoglobulin M 0.54 g/L; Hemoglobin 5.89 mmol/L; Leukocytes 5.07 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 4.9 g/dL; Glucose 4.51 mmol/L.
- Day 822 (ECOG 3): Serum Free Immunoglobulin Light Chain, Kappa 6.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 7.25 g/L; Beta 2 Microglobulin 0.31 µg/mL; Hemoglobin 6.2 mmol/L; Leukocytes 5.77 ×10⁹/L; Absolute Neutrophil 2.73 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.35 mmol/L; Glucose 4.57 mmol/L.
- Day 892: M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 7.38 g/L; Immunoglobulin A 2.15 g/L; Immunoglobulin M 0.77 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 5.55 ×10⁹/L; Absolute Neutrophil 2.73 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.43 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 5.5 mmol/L.
- Day 954: M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Immunoglobulin G 6.33 g/L; Immunoglobulin A 1.94 g/L; Immunoglobulin M 0.6 g/L; Hemoglobin 5.89 mmol/L; Leukocytes 5.25 ×10⁹/L; Absolute Neutrophil 2.74 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 37 g/L; Total Protein 5.6 g/dL; Glucose 4.79 mmol/L.

Other clinical attributes
- Day -4: Weight: 57 kg; Height: 170 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Colorectal Cancer.
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (2 samples)
- Sample MMRF_1997_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_1997_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
